Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0GE, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0GE-TTP1-A (Primary Tumor).

[page 1 of 18]
Pathology Report

PATIENT

PATH #:

AGE: 44 DO

SURGEON:

ADDRESS:

Phwy.

Specimen

RECTAL MASS BXS - EVALUATE FOR CA

ADDENDUM:

**Microsatellite Instability Testing for Lynch's Syndrome (HNPCC) and Sporadic Colon Cancer
By DNA Mismatch Repair (MMR) Protein Expression**

Mismatch Repair Protein

Immunohistochemical Expression*

MLH-1
(Clone ES05)

Nuclear protein expression present ($\geq 1\%$)

MSH-2
(Clone: PE11)

Nuclear protein expression present ($\geq 1\%$)

MSH-6
(Clone: EP49)

Nuclear protein expression present ($\geq 1\%$)

PMS-2
(Clone: EP51)

Nuclear protein expression present ($\geq 1\%$)

*Normal colonic or lymphoid tissue from this patient was also immunostained as a control for the mismatch repair proteins and all proteins were found to be expressed.

Interpretation: There is no loss of MMR nuclear protein expression. This screening study means that Lynch Syndrome is less likely to be the cause of the colorectal cancer in this individual; however, genetic counseling may be appropriate to explain the implication of these test results, especially if there is a personal or family history of colon, endometrial, and/or other cancers.

[page 2 of 18]
Patient Name [REDACTED]

Accession Number [REDACTED]

Birth Date: [REDACTED]

Date Obtained: [REDACTED] +0

Sex: Female [REDACTED]

Date Received: [REDACTED] +1

Final Diagnosis:**COLON, RECTAL MASS, BIOPSIES:****- INVASIVE MODERATELY-DIFFERENTIATED ADENOCARCINOMA.****Comment:**

[REDACTED] has reviewed this case and concurs. Results of this case were discussed with Dr. [REDACTED]. Per our discussion, MSI testing has been ordered and will be resulted as an addendum.

Clinical History / Diagnosis:

CLINICAL DIAGNOSIS: RECTAL MASS.

OTHER INFORMATION: RECTAL BLEEDING, ABNORMAL CT.; Reference Number [REDACTED]

Microscopic Examination:

Sections of the rectal mass show multiple fragments of colonic mucosa and submucosa showing a moderately differentiated adenocarcinoma invading into at least the submucosa, with surrounding mixed inflammation and desmoplasia. Focally abundant mucin production is noted. The surface epithelium is markedly dysplastic. Definitive lymphovascular invasion is not identified.

Gross Examination:

Received in one formalin-filled container, labeled [REDACTED] and "rectal mass bx.'s", are six grey-tan, glistening pieces of tissue, 0.3 to 0.4 cm in greatest dimension, submitted in toto into cassette A1.

[page 3 of 18]
Pathology Report

PATIENT
PATH #
AGE: 44 D

SURGEON:

ADDRESS:
Pkwy.

Specimen

RECTAL MASS BX'S - EVALUATE FOR CA

Final Diagnosis:

COLON, RECTAL MASS, BIOPSIES:

-- INVASIVE MODERATELY-DIFFERENTIATED ADENOCARCINOMA.

Comment:

has reviewed this case and concurs. Results of this case were discussed with Dr. Per our discussion, MSI testing has been ordered and will be resulted as an addendum.

Clinical History / Diagnosis:

CLINICAL DIAGNOSIS: RECTAL MASS.

OTHER INFORMATION: RECTAL BLEEDING, ABNORMAL CT.; Reference Number

Microscopic Examination:

Sections of the rectal mass show multiple fragments of colonic mucosa and submucosa showing a moderately differentiated adenocarcinoma invading into at least the submucosa, with surrounding mixed inflammation and desmoplasia. Focally abundant mucin production is noted. The surface epithelium is markedly dysplastic. Definitive lymphovascular invasion is not identified.

Gross Examination:

Received in one formalin-filled container, labeled and "rectal mass bx.'s", are six grey-tan, glistening pieces of tissue, 0.3 to 0.4 cm in greatest dimension, submitted in toto into cassette A1.

Page 1 of 2

DATE OBTAINED +0
DATE RECEIVED +1
DATE COMPLETE +5

[page 4 of 18]
Patient Name [REDACTED]

Accession Number: [REDACTED]

Birth Date: [REDACTED]

Date Obtained: [REDACTED]

+0

Sex: Female

Date Received: [REDACTED]

+1

[page 5 of 18]
MR#:
ACCT #:
EXAM DATE
ORDERED BY

-1

CT Abdomen and Pelvis With

*** FINAL REPORT ***

Name
MR#
DOB
Sex
Age
Acc#

EXAM REPORT

EXAMINATION: Enhanced CT of the abdomen and pelvis

Date: -1

History: Rectal bleeding intermittently for 2 years. Pain and pressure in the lower abdominal quadrants. Constipation.

Procedure: 76 ml of Isovue 370 were administered intravenously without reaction. Transverse images were obtained through the abdomen and pelvis. Multiprojectional reconstructions were reformatted.

FINDINGS:

Lower chest: No significant abnormality.

Abdomen and retroperitoneum:

Liver: The liver contains 4 subcentimeter hypodense lesions with mildly indistinct margins and with appearance suggesting they could be solid. One lies in the lateral segment left lobe and 3 lie in the right lobe.

Spleen: Normal

Kidneys: Both kidneys show mild pyelocaliectasis. No ureteral dilatation or obstructing lesion is identified. 9 mm left renal fat attenuation, sharply defined nodule compatible with a benign angiomyolipoma. A small nonobstructive left renal calculus is present.

Pancreas: Normal

CT Abdomen and Pelvis With

[page 6 of 18]
MR#:
ACCT #:
EXAM DATE:
ORDERED BY:

-1

CT Abdomen and Pelvis With

Adrenal glands: Normal

Gallbladder: Normal

Biliary tree: Normal

Retroperitoneal and abdominal mass, adenopathy, or fluid collection: None

Major retroperitoneal and upper abdominal vascular structures: No significant abnormality.

Osseous structures: Unilateral right-sided L5 spondylolysis. Mild spinal degenerative changes.

Other findings: None

Pelvis, bowel, and peritoneal compartment:

Bowel: Elongated annular rectal mass extending to near the anal verge is identified. The mass is approximately 8 cm in length. Ill-defined increased density is identified in the perirectal fat and the serosal margin of the rectum is irregular. A few small perirectal nodes are identified a less than 1 cm in diameter. A left posterior pelvic sidewall mass or enlarged internal iliac node is measured on Image 90, series 2, at 2.4 x 2.7 cm. Surrounding edema or tissue infiltration is appreciated.

The colon proximal the rectum is diffusely distended with substantially increased stool. The remainder of the bowel is unremarkable in appearance.

Appendix: Normal appendix visualized.

Non-enteric pelvic viscera: The left ovary is somewhat prominent and contains a 2.3 cm water attenuation cystic lesion that is probably a functional cyst. The right adnexa and uterus are unremarkable. The urinary bladder is distended without focal abnormality or mural thickening.

Mesenteric or pelvic adenopathy: Left posterior pelvic sidewall mass or enlarged internal iliac chain node as discussed above. Multiple small perirectal nodes. No enlarged right iliac chain nodes, left common and external iliac nodes, or mesenteric nodes.

Free peritoneal fluid or gas: Minimal, if any, free peritoneal fluid. Thickening of perirectal fascia.

CT Abdomen and Pelvis With

[page 7 of 18]
MR#:
ACCT #:
EXAM DATE
ORDERED BY

-1

CT Abdomen and Pelvis With

Hernia: Small fat-containing umbilical hernia.

Body wall findings: No significant body wall findings.

Other findings: No significant additional findings.

IMPRESSION:

1. Annular, elongated rectal mass suspicious for primary carcinoma. Potential local invasion and perirectal adenopathy. Enlarged left posterior pelvic sidewall internal iliac node or mass potentially metastatic. Perirectal edema or tumor infiltration and perirectal fascial thickening.
2. Small hypodense lesions with an atypical appearance for cysts in the liver. These are suspicious for metastatic disease.
3. Prominent left ovary containing a hypodense lesion that most likely represents a functional cyst.
4. Distended urinary bladder. Mild bilateral pyelocaliectasis without appreciable obstructing lesion. This is possibly due to stasis related to bladder distention.
5. Small nonobstructing left renal calculus.
6. Small benign left renal angiolipoma.

SLOT 22

CT Abdomen and Pelvis With

[page 8 of 18]
MR#:
ACCT #:
EXAM DATE
ORDERED BY

-1

CT Abdomen and Pelvis With

-1

[page 9 of 18]
CT CHEST/ABD/PELV W CONTRAST [IMG]

Status: Final result

PACS Images

Show images for CT CHEST/ABD/PELV W CONTRAST

Study Result

Result IMPRESSION:

Impression

1. Unchanged asymmetric wall thickening of the rectum with adjacent fat stranding and adjacent 5 mm calcified perirectal nodule.
2. Status post partial right hepatectomy, a single hypodense lesion is seen in segment 2, increased in size, consistent with metastasis.
3. A newly conspicuous 5 mm right lower lobe lung nodule is indeterminate. Recommend attention on followup.

If you are a patient and have a question about your radiology report, please discuss it with your primary care provider.

Result EXAMINATION: CT OF THE CHEST, ABDOMEN, AND PELVIS WITH IV CONTRAST Narrative

DATE: +750

INDICATION: restaging before resecting primary tumor. stage 4 rectal cancer.

TECHNIQUE: Transaxial images of the chest, abdomen, and pelvis were obtained from the apex of the lungs to the ischial tuberosity according to routine chest, abdomen, and pelvis protocol, following the uneventful administration of intravenous contrast material, Isovue 370, 101 ml.

+659

+610 COMPARISON: CT of the abdomen dated CT abdomen
pelvis dated CT chest, abdomen, and pelvis dated

+600

FINDINGS:

CHEST:

Thyroid: No thyroid lesions.

[page 10 of 18]
Thoracic Inlet: No lymphadenopathy

Heart and great vessels: The heart is normal in size. There are no significant atherosclerotic calcifications along the coronary arteries. No pericardial effusion. The great vessels are normal in caliber. A right chest port terminates near the cavoatrial junction.

Mediastinum and hila: There is no significant mediastinal or hilar lymphadenopathy.

Lungs and pleura: A newly prominent 5 mm nodule is seen in the superior segment of the right lower lobe (series [REDACTED]). Either this represents a new nodule or it was obscured by adjacent linear opacities on previous exam. A 6 mm groundglass opacity in the left apex is unchanged (series [REDACTED]). No consolidation, effusion, or pneumothorax.

Chest wall and breasts : The chest walls are unremarkable. . There is no significant supraclavicular or axillary lymphadenopathy.

ABDOMEN AND PELVIS:

Liver: Interval partial right hepatectomy. A hypoenhancing lesion in segment 2 has increased in size from 9 x 6 mm to 13 x 10 mm (series [REDACTED]).

Bile ducts: No intra- or extra-hepatic dilation.

Gallbladder: Surgically absent.

Pancreas: Normal.

Spleen: Borderline splenomegaly.

Adrenals: Normal adrenal glands.

Kidneys/Ureters/Urinary Bladder: No nephrolithiasis or hydronephrosis. Multiple subcentimeter hypodensities are too small to definitively characterize, but statistically likely benign.

Urinary bladder is thin walled and distended.

Reproductive organs:

GI tract/Mesentery: Appendix not identified. No pericecal inflammation. Unchanged asymmetric thickening of the distal rectal wall, measuring 17 x 9 mm (series [REDACTED]) with adjacent fat stranding and a 5 mm calcified perirectal nodule. No obstruction.

Vascular: Aorta and IVC appear normal.

[page 11 of 18]
A tiny amount of free fluid is seen in the pelvis. No free air.
No significant lymphadenopathy in the abdomen and pelvis.
There is mild degenerative change of the spine.

Imaging Contrast/Medications:

iopamidol (ISOVUE 370) 76 % injection 101 mL
Given: 101 mL Intravenous

Exam Information

Status	Exam Begun	Exam Ended
Final [99]	+750	+750

Associated Diagnoses

Rectal cancer metastasized to liver (HC code)

Protocol Summary

Protocol History

Protocolled on	
Protocol:	Chest / Abdomen / Pelvis with Contrast (Single Phase)
Protocol Status:	Protocolled

Patient Care Timeline

No data selected in time range

External Result Report

External Result Report

[page 12 of 18]
Lab Collection Information

Collected: [REDACTED]

Lab IDs

Accession # [REDACTED]

Patient Summary

MRN: [REDACTED] Description: 46 year old female

Description: Female DOB [REDACTED]

CT CHEST/ABD/PELV W CONTRAST (Order

+750

Date and Time: [REDACTED] Department: Radiology CT Scan Ordering Use [REDACTED]

Authorizing: [REDACTED]

Imaging

Reason For Exam

Dx: Rectal cancer metastasized to liver (HC code) [REDACTED]

Order Information

Order Date/Time Release Date/Time Start Date/Time End Date/Time

+750

Order Details

+750

+750

+750

Frequency Duration Priority Order Class
None 1 occurrence Routine Authorization

Order Questions

Question	Answer	Comment
Signs, Symptoms and/or Diagnosis: (e.g. cough):	stage 4 rectal cancer	
Clinical Question: (e.g. eval for pneumonia)	restaging before resecting primary tumor	
OK to be altered by Radiologist	Yes	
Is the Patient Pregnant?	No by patient report or testing	

[page 13 of 18]
Question Answer Comment

Coordinate appointment with ordering clinic? Yes

Pager:

Immediate read?

No

If contrast is ordered is patient at risk of decreased GFR? No known risk

Has the patient had a reaction to CT contrast? No

Protocol Summary

Protocol History

Protocol:

Chest / Abdomen / Pelvis with Contrast (Single Phase)

Protocol Status:

Protooled

Orders Requiring a Screening Form

Procedure

Order Status

Form Status

CT CHEST/ABD/PELV W
CONTRAST

Completed

Form Needed

Collection Information

Collected:

+750

Resulting Agency:

Order Report

View Order Information

There are no specimens.

Order Routing Information

View Order Routing Information

Page

[page 14 of 18]
CT CHEST/ABD/PELV W CONTRAST

Status: Final result

PACS Images

Show images for CT CHEST/ABD/PELV W CONTRAST

Study Result

Result IMPRESSION:

Impression

1. Postsurgical changes as detailed above with no findings of local recurrence or progressing metastatic disease to the chest, abdomen or pelvis.
2. Similar in size parastomal hernia.

If you are a patient and have a question about your radiology report, please discuss it with your primary care provider.

Result EXAMINATION: CT OF THE CHEST, ABDOMEN, AND PELVIS WITH IV CONTRAST Narrative

DATE: [REDACTED] +1456

INDICATION: . Neoplasm: colorectal, rx monitor or f/u.

TECHNIQUE: Transaxial images of the chest, abdomen, and pelvis were obtained from the apex of the lungs to the ischial tuberosity according to according to routine chest, abdomen, and pelvis protocol, following the uneventful administration of intravenous contrast material, Isovue 370, 85 ml.

COMPARISON: [REDACTED] and [REDACTED]

FINDINGS: +1355 +1195

CHEST:

Thyroid: No thyroid lesions.

Mediastinum and hila: Normal contrast enhancement of the great vessels. No filling defects seen within the pulmonary arteries. Central airways are clear. A prominent right upper paratracheal

[page 15 of 18]
node is stable in size measuring 11 mm in short axis. No other prominent mediastinal or hilar nodes.

Heart and pericardium: The heart size within normal limits. There are no significant coronary artery calcifications. No pericardial effusion.

Chest wall and breasts: Stable right chest port with the distal catheter tip within the cavoatrial junction. Chest wall otherwise normal. There is no axillary or supraclavicular lymphadenopathy.

Lungs and pleura: Partial lobectomy of the right lower lobe with associated scarring and similar from the comparisons. Lung volumes otherwise symmetric. No suspicious pulmonary nodules. No airspace or interstitial lung disease. No pleural effusion.

ABDOMEN AND PELVIS:

Liver: Stable postsurgical changes consistent with a partial right hepatectomy. No surrounding fluid collection. No subjacent suspicious osseous lesions or soft tissue nodularity to suggest recurrence. Compensatory hypertrophy of the left hepatic lobe remain similar from the comparisons. Patent hepatic and portal veins.

Bile ducts: No intra- or extra-hepatic dilation.

Gallbladder: Surgically absent.

Pancreas: Symmetric pancreatic enhancement with no solid or cystic pancreatic lesions. No pancreatic duct dilatation.

Spleen: No splenomegaly.

Adrenals: Normal adrenal glands.

Kidneys/Ureters/Urinary Bladder: Symmetric renal cortical enhancement. There is a stable 8 mm AML seen in the interpolar left renal cortex. There is a similar in size 8 mm hypodense cortical lesion in the superior medial cortex of the right kidney. Findings too small to accurately characterize, but probably represents a renal cyst. Unchanged bilateral extrarenal pelvis and presumed small peripelvic cysts. No obstructive uropathy. Ureters normal in course and caliber. Urinary bladder is thin walled and distended.

Reproductive organs: No solid or cystic adnexal lesions.

GI tract/Mesentery: Postsurgical changes consistent with a partial left hemicolectomy with diverting colostomy in the left lower quadrant, similar from the comparisons. Stable presacral postoperative fat stranding and fluid with otherwise no inflammatory fat stranding or mesenteric edema. No obstruction.

Vascular: Aorta and IVC appear normal.

[page 16 of 18]
No free air. No free fluid.

Lymph nodes: No significant lymphadenopathy in the abdomen and pelvis.

Bones and soft tissues: There is mild degenerative change of the spine. No aggressive osseous lesions or acute osseous findings. Similar in size fat-containing parastomal hernia in the left lower quadrant. There is a bilateral L5 spondylolysis without evidence of anterolisthesis.

Imaging Contrast/Medications:

iopamidol (ISOVUE 370) 76 % injection 85 mL
Given: 85 mL Intravenous

📌 Encounter Medications

Encounter Medications Report (

Exam Information

Status		Exam Begun	Exam Ended
Final [99]	+1456		+1456

Associated Diagnoses

Rectal cancer, metastatic to liver
Malignant neoplasm metastatic to right lung (HC code)

Protocol Summary

Protocol History

Protocolled on
Protocols: Chest / Abdomen / Pelvis with Contrast (Single Phase)
Protocol Status: Protocolled

Patient Care Timeline

[page 17 of 18]
No data selected in time range

External Result Report

External Result Report

Lab Collection Information

Collected: [REDACTED] +1457

Lab IDs

Accession # [REDACTED]

MRN [REDACTED] Patient Summary
Description: 48 year old female

Description: Female DOB: [REDACTED]

CT CHEST/ABD/PELV W CONTRAST (Order

+1456

Date and Time [REDACTED] Department: Radiology CT Scan Ordering Use [REDACTED]
Authorizing: [REDACTED]

Imaging

Reason For Exam

Neoplasm: colorectal, rx monitor or f/u

Dx: Rectal cancer, metastatic to liver [REDACTED] Malignant neoplasm metastatic to right lung (HC code) [REDACTED]

Order Questions

[page 18 of 18]
Question	Answer	Comment
OK to be altered by Radiologist	Yes	
Coordinate appointment with ordering clinic?	Yes	
Pager:		
Immediate read?	No	
If contrast is ordered is patient at risk of decreased GFR?	Has hypertension	
Has the patient had a reaction to CT contrast?	No	

Protocol Summary

Protocol History

Protocolled on	
Protocols:	Chest / Abdomen / Pelvis with Contrast (Single Phase)
Protocol Status:	Protocolled

Orders Requiring a Screening Form

Procedure	Order Status	Form Status
CT CHEST/ABD/PELV W CONTRAST	Completed	In Progress

Collection Information

Collected:	+1457	Resulting Agency:
------------	-------	-------------------

Order Report

[View Order Information](#)

There are no specimens.

Order Routing Information

[View Order Routing Information](#)

Page

Source: NCI Genomic Data Commons file 7598e672-b47c-42b3-81ef-787186536171 (ER0395 ER-B0GE Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).